Somatic mutation profile of tumor specimen TCGA-B5-A0JR-01A (aliquot TCGA-B5-A0JR-01A-13W-A062-09) from TCGA case TCGA-B5-A0JR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.4 years (26,814 days).
Specimen TCGA-B5-A0JR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0761bfc-d493-4d8e-be78-47b2d8889a6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JR-10A (Blood Derived Normal), aliquot TCGA-B5-A0JR-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9cb72eb-47a0-4db8-b8bd-3cbfc49bc9dd

The open-access MAF lists 760 somatic variants for this specimen: 560 protein-altering or splice-affecting, 177 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 389, Silent 177, Frame Shift Del 92, Frame Shift Ins 31, Nonsense Mutation 28, Splice Site 13, Intron 11, Splice Region 5, 3'Flank 5, RNA 2, 5'UTR 2, 5'Flank 2.

Variants (750 of 760; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A3 | c.1163G>A p.R388H (on ENST00000545399 / NM_001256214.2; = p.R375H on NM_152296.5) | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200891944, COSV57486868; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCM2 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as rs137852841, CM033594, COSV51847794; ClinVar: pathogenic; called by muse, mutect2
- CEP290 | c.1666del p.I556Ffs*17 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | catalogued as rs727503855, CD073590; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FGFR2 | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519795, COSV60638890; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GJB6 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); catalogued as rs104894414, CM993506, COSV53831918; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIAA0586 | c.-8dup | 5'UTR (INS) | VAF 17/64 reads (27%) | catalogued as rs745949846; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 68/152 reads (45%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 94/310 reads (30%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 75/180 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2, varscan2
- RPGRIP1L | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as rs751477523, CM1212113, COSV50905127; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.1655G>T p.R552M | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397517154, CM070273, CM095735, CM116030, COSV67674782, COSV67675536; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TRIOBP | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 163/420 reads (39%) | catalogued as rs118204026, CM067723, COSV60376201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABAT | c.778A>C p.K260Q | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV51622210; called by muse, mutect2, varscan2
- ABCC10 | c.2314A>G p.M772V (on ENST00000372530 / NM_001198934.2; = p.M744V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV55086704; called by muse, mutect2, varscan2
- ACSM1 | c.1648-1G>A p.X550_splice | Splice Site (SNP) | VAF 106/245 reads (43%) | catalogued as COSV54634858; called by muse, mutect2, varscan2
- ACSM4 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs79217312, COSV68066927, COSV68069170; called by muse, mutect2, varscan2
- ACTR2 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs757353258, COSV53199530; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 64/181 reads (35%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCY1 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs143601874, COSV52029598, COSV52031488; called by muse, mutect2, varscan2
- ADCY9 | c.1828T>C p.S610P | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.593); catalogued as COSV53574192; called by muse, mutect2, varscan2
- AGL | c.4316T>C p.L1439P | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV54051479; called by muse, mutect2, varscan2
- AGPS | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51563103; called by muse, mutect2, varscan2
- AHCY | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs199533546, COSV54152885; called by muse, mutect2, varscan2
- AK7 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs781727092, COSV50870814; called by muse, mutect2, varscan2
- AKAP13 | c.6923C>T p.P2308L (on ENST00000394518 / NM_007200.5; = p.P2312L on NM_006738.6) | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63454206; called by muse, mutect2, varscan2
- AKAP17A | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs759121022, COSV58309239; called by muse, mutect2, varscan2
- ALDH3B2 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV62427990; called by muse, mutect2, varscan2
- ALS2 | c.974T>C p.M325T | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV51886211; called by muse, mutect2, varscan2
- AMER1 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57659228; called by muse, mutect2, varscan2
- ANAPC15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs982888986, COSV56191427; called by muse, mutect2, varscan2
- ANO7 | c.1558C>A p.L520M (on ENST00000274979; = p.L466M on NM_001370694.2) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.683); catalogued as COSV51470746; called by muse, mutect2, varscan2
- AOX1 | c.3689C>T p.T1230I | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs143363067, COSV53495798; called by muse, mutect2, varscan2
- AP1G2 | c.893T>C p.M298T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1479430378, COSV55337938; called by muse, mutect2, varscan2
- AP2M1 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs756877807, COSV53047729; called by muse, mutect2, varscan2
- AP3B1 | c.3126A>G p.I1042M | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV54881798; called by muse, mutect2
- APAF1 | c.3184T>C p.S1062P (on ENST00000551964 / NM_181861.2; = p.S1008P on NM_001160.3) | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59663489; called by muse, mutect2, varscan2
- APCS | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 72/375 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54817823; called by muse, mutect2, varscan2
- ARAP3 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs368544318; called by muse, mutect2, varscan2
- ARHGEF15 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV62724909, COSV62726004; called by muse, mutect2, varscan2
- ARSB | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV53723093; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs753865255; called by mutect2, varscan2
- ASCC3 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs767266213, COSV61227769; called by muse, mutect2, varscan2
- ASH1L | c.6494T>G p.L2165R (on ENST00000368346 / NM_001366177.2; = p.L2160R on NM_018489.3) | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64207191; called by muse, mutect2, varscan2
- ATF6 | c.247G>T p.V83F | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.039); catalogued as COSV63407082; called by muse, mutect2, varscan2
- ATM | c.7089G>T p.K2363N | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV53738684; called by muse, mutect2, varscan2
- ATP10D | c.1498A>G p.S500G | Missense Mutation (SNP) | VAF 93/360 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1300826153, COSV56706545; called by muse, mutect2, varscan2
- ATP1A3 | c.2939C>T p.A980V (on ENST00000545399 / NM_001256214.2; = p.A967V on NM_152296.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV57486860; called by muse, mutect2, varscan2
- ATP2A3 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV59228160; called by muse, mutect2, varscan2
- ATP6V0A1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs565034112, COSV52872300; called by muse, mutect2, varscan2
- ATR | c.7547C>T p.T2516I | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63384257; called by muse, mutect2, varscan2
- ATRNL1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61802459; called by muse, mutect2, varscan2
- BCAN | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs769524070, COSV61256461; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 32/79 reads (41%) | catalogued as rs752427670; called by mutect2, varscan2
- BNIPL | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 81/403 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV54846597; called by muse, mutect2, varscan2
- BRWD3 | c.1642T>C p.Y548H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV64746834; called by muse, mutect2, varscan2
- BUB1B | c.2363_2364del p.S788Cfs*29 | Frame Shift Del (DEL) | VAF 37/143 reads (26%) | catalogued as rs756459860; called by pindel, varscan2
- C12orf71 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs763196274, COSV70282645; called by muse, mutect2, varscan2
- C16orf72 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as COSV59915879; called by muse, mutect2, varscan2
- C3orf20 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53784495; called by muse, mutect2, varscan2
- CA8 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58771617; called by muse, mutect2, varscan2
- CABP2 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.194); catalogued as rs374871134, COSV53708746; called by muse, mutect2, varscan2
- CACNA1A | c.1946C>T p.T649I | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64195684; called by muse, mutect2, varscan2
- CACNA1S | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV62938688; called by muse, mutect2
- CAD | c.968T>C p.I323T | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV53025725; called by muse, mutect2, varscan2
- CBWD2 | c.885+2T>C p.X295_splice | Splice Site (SNP) | VAF 135/446 reads (30%) | catalogued as COSV52073843; called by muse, mutect2, varscan2
- CCDC102B | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368864406; called by muse, mutect2, varscan2
- CCDC120 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs367814991; called by muse, mutect2
- CCDC178 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as COSV55769426; called by muse, mutect2, varscan2
- CCKBR | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as COSV58100556; called by muse, mutect2, varscan2
- CCNG1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV57084500; called by muse, mutect2, varscan2
- CCNH | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 128/301 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs201354427, COSV56924664; called by muse, mutect2, varscan2
- CCT8L2 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as rs374451524, COSV100743070; called by muse, mutect2, varscan2
- CD4 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV50590200; called by muse, mutect2, varscan2
- CDCA4 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs762874162, COSV60315280; called by muse, mutect2, varscan2
- CDHR3 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs368274712; called by muse, mutect2, varscan2
- CDK17 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 80/187 reads (43%) | catalogued as COSV54128293; called by muse, mutect2, varscan2
- CENPI | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV54501852, COSV99515609; called by muse, mutect2, varscan2
- CEP128 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs200135744, COSV55373956; called by muse, mutect2, varscan2
- CEP44 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213012742, COSV56659113; called by muse, mutect2, varscan2
- CFLAR | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57936754; called by muse, mutect2
- CHPF | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60534420; called by muse, mutect2, varscan2
- CHRM3 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs144239896; called by muse, mutect2, varscan2
- CHRNB2 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297214421, COSV63807650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNG | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs139633799; called by muse, varscan2
- CLCN5 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs782014653, COSV56583462; called by muse, mutect2, varscan2
- CLTCL1 | c.4227G>T p.Q1409H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs782094703, COSV54228623; called by muse, mutect2, varscan2
- CLUL1 | c.124del p.E42Rfs*2 | Frame Shift Del (DEL) | VAF 55/201 reads (27%) | catalogued as rs770141560; called by mutect2, pindel, varscan2
- CMTR2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs578011693, COSV57603152, COSV57603758; called by muse, mutect2, varscan2
- CNTN2 | c.2968G>A p.G990R | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753710924, COSV59348323; called by muse, mutect2, varscan2
- CNTN6 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63168987; called by muse, mutect2, varscan2
- CNTNAP4 | c.2155C>A p.L719I | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56675308, COSV99048721; called by muse, varscan2
- COL16A1 | c.2538G>T p.P846= | Splice Region (SNP) | VAF 11/41 reads (27%) | catalogued as COSV54704087, COSV54705041; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 16/48 reads (33%) | catalogued as rs760493024; called by mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as COSV101232229; called by mutect2, pindel, varscan2
- COPB2 | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV60349635; called by muse, mutect2, varscan2
- COQ8A | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs758986425, COSV62009198; called by muse, mutect2, varscan2
- CPEB1 | c.1203G>A p.W401* (on ENST00000617958; = p.W341* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV55618464; called by muse, mutect2, varscan2
- CRYBG3 | c.7294C>T p.L2432F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51711168; called by muse, mutect2, varscan2
- CSMD3 | c.3623G>A p.C1208Y (on ENST00000297405 / NM_001363185.1; = p.C1104Y on NM_052900.3) | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52155965; called by muse, mutect2, varscan2
- CUL2 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs1378650744, COSV66078995; called by muse, mutect2, varscan2
- CXorf38 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV59947462; called by muse, mutect2, varscan2
- CYP4X1 | c.608G>A p.C203Y | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV64150447; called by muse, mutect2, varscan2
- DCAF12L1 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64421589; called by muse, mutect2, varscan2
- DCAF6 | c.2150G>A p.R717H (on ENST00000312263 / NM_001349778.1; = p.R737H on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV56577624; called by muse, mutect2, varscan2
- DCAF8L1 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs749236143, COSV71595229; called by muse, mutect2, varscan2
- DCTN4 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV69782067; called by muse, mutect2, varscan2
- DDB1 | c.2234C>T p.T745M | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs771961884, COSV57102295; called by muse, mutect2, varscan2
- DDIT4 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1564804824, COSV56577335; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX31 | c.532del p.M178Cfs*42 | Frame Shift Del (DEL) | VAF 95/307 reads (31%) | catalogued as rs1352828170; called by mutect2, pindel, varscan2
- DDX47 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1364495449, COSV61911389; called by muse, mutect2, varscan2
- DEFB104A | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV58629839; called by mutect2, varscan2
- DEFB129 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV55731238, COSV55731310; called by muse, mutect2, varscan2
- DEPDC5 | c.2182C>T p.R728C (on ENST00000400246; = p.R797C on NM_014662.5) | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953743301, COSV56695437; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKE | c.1418A>G p.D473G | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV52349522; called by muse, mutect2, varscan2
- DGKK | c.3022G>T p.V1008L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65707099; called by muse, mutect2, varscan2
- DHX16 | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs757343846, COSV53313495; called by muse, mutect2, varscan2
- DHX29 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52417787; called by muse, mutect2, varscan2
- DHX38 | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51697438; called by muse, mutect2, varscan2
- DLAT | c.1790T>C p.L597P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV54770173; called by muse, mutect2, varscan2
- DMAC2 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs782756554, COSV55727951; called by muse, mutect2, varscan2
- DMD | c.8851C>T p.R2951C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs760516307, COSV58896066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMXL1 | c.5980G>A p.D1994N | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs771566108, COSV60709345; called by muse, mutect2, varscan2
- DNAH10 | c.2876C>A p.T959N (on ENST00000409039; = p.T898N on NM_207437.3) | Missense Mutation (SNP) | VAF 331/925 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV68991858; called by muse, mutect2
- DNAH3 | c.11629A>G p.R3877G | Missense Mutation (SNP) | VAF 143/428 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV54516065; called by muse, mutect2, varscan2
- DNAH7 | c.4707G>T p.L1569F | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.022); catalogued as COSV56760252; called by muse, mutect2, varscan2
- DNAH8 | c.10312-2A>C p.X3438_splice | Splice Site (SNP) | VAF 125/335 reads (37%) | catalogued as COSV59438809; called by muse, mutect2, varscan2
- DNAH9 | c.10591A>T p.K3531* | Nonsense Mutation (SNP) | VAF 41/101 reads (41%) | catalogued as rs200261738, COSV52345258; called by muse, mutect2, varscan2
- DOCK11 | c.4549A>C p.K1517Q | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as COSV52237263; called by muse, mutect2, varscan2
- DOCK3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.354); catalogued as rs200043819, COSV56514300; called by muse, mutect2, varscan2
- DOCK3 | c.4205A>G p.H1402R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.424); catalogued as COSV56515635; called by muse, mutect2
- DOCK4 | c.5478del p.S1827Lfs*43 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs759180337; called by mutect2, varscan2
- DPM3 | c.46T>C p.S16P (on ENST00000341298; = p.S46P on NM_018973.3) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV57596639; called by muse, mutect2, varscan2
- DPPA2 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs766319393, COSV72118022; called by muse, mutect2, varscan2
- DRD5 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58577614; called by muse, mutect2, varscan2
- DROSHA | c.2482del p.I828Yfs*7 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs1471632102; called by mutect2, varscan2
- DSCAM | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs780886519, COSV68025073; called by muse, mutect2, varscan2
- DSEL | c.2791G>A p.G931S | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59490776, COSV59493714; called by muse, mutect2, varscan2
- DSP | c.7048T>G p.L2350V | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65792311; called by muse, mutect2, varscan2
- DST | c.21995C>A p.P7332H (on ENST00000361203 / NM_001374722.1; = p.P5005H on NM_015548.5) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV55009064; called by muse, mutect2
- DST | c.7609G>T p.G2537* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | catalogued as COSV55009074; called by muse, mutect2, varscan2
- EGLN2 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs1234683261, COSV58279712; called by muse, mutect2, varscan2
- EIF2A | c.1688del p.N563Ifs*31 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | catalogued as COSV99855990; called by mutect2, pindel, varscan2
- EIF2B3 | c.615C>A p.Y205* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV64517257; called by muse, mutect2, varscan2
- EIF4B | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as COSV50402313; called by muse, mutect2, varscan2
- ENOX1 | c.1892G>A p.R631K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs1262250598, COSV54895757; called by muse, mutect2, varscan2
- EPHB4 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62268607; called by muse, mutect2
- EPHX2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV66844577, COSV66844783; called by muse, mutect2, varscan2
- EPS8 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1417611290, COSV55529686; called by muse, mutect2, varscan2
- FAM189B | c.1889G>A p.C630Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV59169552; called by muse, mutect2, varscan2
- FAT3 | c.11786C>T p.T3929M | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs750266585, COSV53099623; called by muse, varscan2
- FCSK | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs1350324912, COSV55369806; called by muse, mutect2, varscan2
- FIGNL1 | c.661T>C p.F221L | Missense Mutation (SNP) | VAF 128/223 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV63553381; called by muse, mutect2, varscan2
- FN1 | c.7100G>A p.C2367Y (on ENST00000359671 / NM_001365524.2; = p.C2336Y on NM_002026.4) | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1559295426, COSV60550688; called by muse, mutect2, varscan2
- FOCAD | c.4123G>A p.G1375R | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771075968, COSV58097224, COSV58103915; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs752538869; called by mutect2, pindel
- FRS2 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV54724842; called by muse, mutect2, varscan2
- GALNT10 | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as rs1205768103, COSV51725241; called by muse, mutect2, varscan2
- GALNT15 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100327502, COSV60216550; called by muse, mutect2, varscan2
- GAP43 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV59343604; called by muse, mutect2, varscan2
- GCC1 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV58462291; called by muse, mutect2, varscan2
- GCNA | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65466059; called by muse, mutect2, varscan2
- GGH | c.825dup p.V276Cfs*2 | Frame Shift Ins (INS) | VAF 69/183 reads (38%) | catalogued as rs747800974; called by mutect2, varscan2
- GNAT3 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as rs772886967, COSV68068453; called by muse, mutect2, varscan2
- GNE | c.623G>A p.R208H (on ENST00000396594 / NM_001128227.3; = p.R177H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs772597073, COSV64951377; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GOLM1 | c.1134del p.F378Lfs*11 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs1477670534; called by mutect2, pindel, varscan2
- GPATCH1 | c.279T>G p.D93E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50113383; called by muse, mutect2, varscan2
- GPD2 | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60092070; called by muse, mutect2
- GPRIN1 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56137556; called by muse, mutect2, varscan2
- H1-1 | c.238A>G p.N80D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55119197; called by muse, mutect2, varscan2
- HADHA | c.138A>C p.K46N | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV66107047; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs746547303; called by mutect2, varscan2
- HDHD5 | c.887C>T p.A296V (on ENST00000336737 / NM_033070.3; = p.A266V on NM_017829.5) | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs770984387, COSV50085216; called by muse, mutect2, varscan2
- HEATR1 | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1278961171, COSV63980730; called by muse, mutect2, varscan2
- HECTD4 | c.2521T>C p.Y841H | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.712); catalogued as COSV61178750; called by muse, mutect2, varscan2
- HELLS | c.461del p.N154Ifs*29 | Frame Shift Del (DEL) | VAF 31/74 reads (42%) | catalogued as rs775038246; called by mutect2, varscan2
- HMCN1 | c.7974C>A p.H2658Q | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54893234; called by muse, mutect2, varscan2
- HMMR | c.1912dup p.I638Nfs*10 | Frame Shift Ins (INS) | VAF 25/82 reads (30%) | catalogued as rs774501154; called by mutect2, pindel, varscan2
- HNRNPM | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.575); catalogued as COSV55313226, COSV99725232; called by muse, mutect2, varscan2
- HOMEZ | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100664215, COSV62536786; called by muse, mutect2, varscan2
- HOOK1 | c.1089del p.A364Qfs*8 | Frame Shift Del (DEL) | VAF 57/183 reads (31%) | catalogued as COSV64619270; called by mutect2, pindel, varscan2
- HRNR | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV64256851; called by muse, mutect2, varscan2
- ICE1 | c.5447A>G p.D1816G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56822680; called by muse, mutect2, varscan2
- IDE | c.2861T>C p.V954A | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV56422719; called by muse, mutect2, varscan2
- IFI16 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1245013193, COSV55533115; called by muse, mutect2, varscan2
- IGF2BP2 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60485009; called by muse, mutect2, varscan2
- IGHM | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.74); catalogued as rs374540831; called by muse, mutect2
- IGSF9B | c.2380T>C p.S794P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV58066399; called by muse, mutect2, varscan2
- IKBKE | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV65625175; called by muse, mutect2
- ING2 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100180510, COSV56564027; called by muse, mutect2, varscan2
- INO80D | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as rs771067196, COSV68958666; called by muse, mutect2, varscan2
- INTU | c.1462A>G p.M488V | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58870921; called by muse, mutect2, varscan2
- IPO9 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV64233441; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.003); catalogued as COSV67332181; called by muse, mutect2, varscan2
- IRS1 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1203645968, COSV59334053, COSV59335444; called by muse, mutect2, varscan2
- ITGA2B | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.596); catalogued as rs758048588, COSV52232173; called by muse, mutect2, varscan2
- ITPR3 | c.7571G>A p.R2524H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65268237; called by muse, mutect2
- JADE3 | c.2104G>A p.G702S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV54465881; called by muse, mutect2, varscan2
- KCNA7 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs1263211065, COSV55503184; called by muse, mutect2, varscan2
- KCNK3 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV57192224; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | catalogued as rs771351714; called by mutect2, varscan2
- KDSR | c.818T>C p.M273T | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV58506692; called by muse, mutect2, varscan2
- KHDRBS1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs375097901; called by muse, mutect2, varscan2
- KIAA0100 | c.4171G>A p.V1391I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.969); catalogued as rs757697591, COSV66492040; called by muse, mutect2, varscan2
- KIAA0232 | c.3390A>C p.K1130N | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV56924598; called by muse, mutect2, varscan2
- KIAA1191 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV53798772; called by muse, mutect2, varscan2
- KIAA1614 | c.2021A>G p.Q674R | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV62550730; called by muse, mutect2, varscan2
- KIF18B | c.1550G>A p.R517Q (on ENST00000593135 / NM_001265577.2; = p.R529Q on NM_001264573.2) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs778886621, COSV100192335, COSV59272384; called by muse, mutect2
- KIF5A | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV54053674; called by muse, mutect2, varscan2
- KIF5C | c.1398A>G p.I466M | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV68480740; called by muse, mutect2, varscan2
- KIF9 | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55519019; called by muse, mutect2, varscan2
- KIT | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.417); catalogued as COSV55396772; called by muse, varscan2
- KLB | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV57301194; called by muse, mutect2, varscan2
- KMT2C | c.7365T>G p.Y2455* | Nonsense Mutation (SNP) | VAF 74/289 reads (26%) | catalogued as COSV51429739; called by muse, mutect2, varscan2
- KNDC1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs777184792, COSV58835227; called by muse, mutect2, varscan2
- KRTAP10-9 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV59958745, COSV59966335; called by muse, mutect2, varscan2
- KRTAP6-2 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 51/113 reads (45%) | PolyPhen probably damaging (0.999); catalogued as rs767130290, COSV100588953, COSV58182077; called by muse, mutect2, varscan2
- KSR2 | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV60373359; called by muse, mutect2
- L1CAM | c.3251C>T p.T1084I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV62827741; called by muse, mutect2, varscan2
- LAMB4 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV52717389; called by muse, mutect2, varscan2
- LARP1 | c.1337G>T p.R446L (on ENST00000518297 / NM_033551.3; = p.R369L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60426330; called by muse, mutect2, varscan2
- LAX1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 84/353 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as rs778286533, COSV65849185; called by muse, mutect2, varscan2
- LBR | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.046); catalogued as rs765875442, COSV55288281; called by muse, mutect2, varscan2
- LCA5L | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780853140, COSV55744844; called by muse, mutect2, varscan2
- LHFPL4 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV55001840; called by muse, mutect2, varscan2
- LIN28A | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54261617; called by muse, mutect2, varscan2
- LLGL2 | c.2530C>T p.R844W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51344009; called by muse, varscan2
- LMBRD1 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as rs1273479747, COSV65296864; called by muse, mutect2
- LRBA | c.8552A>G p.D2851G | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV63953329; called by muse, mutect2, varscan2
- LRP12 | c.2255A>G p.Q752R | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.932); catalogued as COSV52627773; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 108/288 reads (38%) | catalogued as rs1557715031, COSV58440688; called by mutect2, varscan2
- LZTR1 | c.1979A>G p.E660G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as COSV53146768; called by muse, mutect2, varscan2
- LZTS3 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs761681400, COSV61277502; called by muse, varscan2
- MACF1 | c.3730C>T p.R1244C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as rs765564021, COSV58369365; called by muse, mutect2, varscan2
- MACF1 | c.10521T>G p.N3507K | Missense Mutation (SNP) | VAF 53/134 reads (40%) | catalogued as COSV57117504; called by muse, mutect2, varscan2
- MAGEB3 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV64396955; called by muse, mutect2, varscan2
- MAGED1 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs782675141, COSV58515023; ClinVar: uncertain significance; called by muse, mutect2
- MAGEL2 | c.2766G>T p.W922C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV58566656; called by muse, mutect2, varscan2
- MAP2K2 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.077); catalogued as rs762635761, COSV53564337; called by muse, mutect2, varscan2
- MAP3K12 | c.1605dup p.S536Lfs*35 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs779220145; called by mutect2, varscan2
- MAP7D1 | c.107dup p.P37Tfs*24 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs749986670; called by mutect2, varscan2
- MAPK10 | c.111G>T p.Q37H (on ENST00000359221 / NM_001351625.2; = p.Q75H on NM_002753.5) | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV60380358, COSV60382747; called by muse, mutect2, varscan2
- MAPK8 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV64408800; called by muse, mutect2, varscan2
- MAPKAPK2 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs782022011, COSV54315633; called by muse, mutect2, varscan2
- MCMBP | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV63508983; called by muse, mutect2, varscan2
- MCOLN3 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 26/757 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158927529, COSV62013800; called by muse, mutect2
- MECOM | c.613C>G p.R205G (on ENST00000468789 / NM_001105078.4; = p.R393G on NM_004991.4) | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201758074, COSV52963046, COSV52964249, COSV52973072; called by muse, mutect2, varscan2
- MGA | c.3157C>T p.R1053* | Nonsense Mutation (SNP) | VAF 61/157 reads (39%) | catalogued as COSV54952158; called by muse, mutect2, varscan2
- MIA3 | c.3982-2A>G p.X1328_splice | Splice Site (SNP) | VAF 61/307 reads (20%) | catalogued as rs775427677, COSV60511937; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | catalogued as rs749903408; called by mutect2, varscan2
- MME | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV64706929; called by muse, mutect2, varscan2
- MOGS | c.1718T>C p.L573P | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51968919; called by muse, mutect2
- MON2 | c.2662G>A p.V888M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs201327821, COSV54805911; called by muse, mutect2, varscan2
- MROH7 | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs747802963, COSV59870870; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MSRB3 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57590376; called by muse, mutect2
- MYO3A | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.196); catalogued as COSV56327313; called by muse, mutect2, varscan2
- MYOC | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 47/207 reads (23%) | catalogued as rs202176570, CM005409, CM087800; called by muse, mutect2, varscan2
- NAGK | c.146T>A p.I49N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54903377; called by muse, mutect2, varscan2
- NAGLU | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV56794626; called by muse, mutect2, varscan2
- NCAPG2 | c.2039C>A p.A680D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV51986831; called by muse, mutect2, varscan2
- NDST2 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as COSV55213930; called by muse, mutect2, varscan2
- NDUFA13 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs779884184, COSV53063243; called by muse, mutect2, varscan2
- NDUFC1 | c.172-2A>G p.X58_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV55499404; called by muse, mutect2, varscan2
- NEK6 | c.381_382insT p.G128Wfs*11 | Frame Shift Ins (INS) | VAF 7/21 reads (33%) | catalogued as COSV100206977; called by mutect2, pindel, varscan2
- NFATC3 | c.1602-2A>G p.X534_splice | Splice Site (SNP) | VAF 33/77 reads (43%) | catalogued as COSV60473026; called by muse, mutect2, varscan2
- NFYC | c.886-2A>T p.X296_splice (on ENST00000308733 / NM_001308114.1; = p.X277_splice on NM_014223.5) | Splice Site (SNP) | VAF 52/168 reads (31%) | catalogued as COSV58126813; called by muse, mutect2, varscan2
- NHSL2 | c.392G>A p.R131Q (on ENST00000510661; = p.R497Q on NM_001013627.2) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764033024, COSV65453097; called by muse, mutect2, varscan2
- NKAPL | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1473256908, COSV59197224; called by muse, mutect2, varscan2
- NOP16 | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1480617288, COSV51257535; called by muse, mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 58/191 reads (30%) | catalogued as rs35747263; called by mutect2, pindel, varscan2
- NPC1L1 | c.1205G>C p.G402A | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV56924244; called by muse, mutect2, varscan2
- NSD1 | c.7391G>A p.R2464H | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs587784216, COSV61774851; ClinVar: benign; called by muse, mutect2, varscan2
- NSD2 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV56389391; called by muse, mutect2, varscan2
- NUCKS1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs758268939, COSV65652687; called by muse, mutect2, varscan2
- NVL | c.1985C>A p.A662D | Missense Mutation (SNP) | VAF 105/517 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55871662, COSV55875060; called by muse, mutect2, varscan2
- OBSCN | c.14717A>G p.D4906G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV52763905; called by muse, mutect2, varscan2
- OLFML3 | c.795del p.Y266Tfs*3 | Frame Shift Del (DEL) | VAF 60/169 reads (36%) | catalogued as rs753594963; called by mutect2, pindel, varscan2
- OR10J1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 76/352 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV101419913, COSV71128678; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 34/182 reads (19%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2B2 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57579466; called by muse, mutect2, varscan2
- OR2G3 | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 130/1090 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60681374; called by muse, mutect2, varscan2
- OR5B21 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV64481779; called by muse, mutect2, varscan2
- OR5M3 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.044); catalogued as COSV56566494; called by muse, mutect2, varscan2
- PABPC4 | c.1693dup p.Q565Pfs*37 | Frame Shift Ins (INS) | VAF 14/24 reads (58%) | catalogued as rs769044699; called by mutect2, varscan2
- PAOX | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1472318687, COSV53371964; called by muse, mutect2, varscan2
- PARD6B | c.197A>G p.H66R | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV65404345; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | catalogued as rs758945932; called by mutect2, varscan2
- PCDHA1 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV65373779; called by muse, mutect2, varscan2
- PCDHA4 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV63540150; called by muse, mutect2, varscan2
- PCDHA6 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs536607224, COSV65343503; called by muse, mutect2, varscan2
- PCDHA7 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as rs782425324, COSV65342157, COSV65347667; called by muse, mutect2, varscan2
- PCDHB15 | c.829A>C p.I277L | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as COSV50891985; called by muse, mutect2, varscan2
- PCDHB6 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV50693959, COSV50697942; called by muse, mutect2, varscan2
- PCDHGA3 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as COSV53930602; called by muse, mutect2, varscan2
- PCDHGA5 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1391136210, COSV53930613; called by muse, mutect2, varscan2
- PCLO | c.5683C>T p.P1895S | Missense Mutation (SNP) | VAF 115/410 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371461306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE4DIP | c.3194A>G p.E1065G | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.422); catalogued as COSV57690850; called by muse, mutect2, varscan2
- PDGFC | c.974C>G p.T325S | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV56847667; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 78/132 reads (59%) | catalogued as rs747131399; called by mutect2, varscan2
- PDZRN4 | c.3104C>T p.T1035I (on ENST00000402685 / NM_001164595.2; = p.T777I on NM_013377.4) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54198440; called by muse, mutect2, varscan2
- PHKA2 | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs368131175, COSV66053063, COSV66055712; called by muse, mutect2, varscan2
- PHLPP2 | c.3230C>A p.A1077D | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62423952; called by muse, mutect2, varscan2
- PIK3C2A | c.340del p.T114Hfs*10 | Frame Shift Del (DEL) | VAF 90/312 reads (29%) | catalogued as COSV56402935; called by mutect2, pindel, varscan2
- PIK3R1 | c.1718T>C p.L573P (on ENST00000521381 / NM_181523.3; = p.L303P on NM_181504.4) | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57124674; called by muse, mutect2, varscan2
- PIK3R4 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs776446334, COSV63240359; called by muse, mutect2, varscan2
- PIWIL2 | c.2287A>C p.S763R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63250987; called by muse, mutect2, varscan2
- PKHD1L1 | c.9670C>A p.L3224I | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV65740444; called by muse, mutect2, varscan2
- PLA2R1 | c.356G>T p.R119M | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as COSV51777510; called by muse, mutect2, varscan2
- PLCE1 | c.4060G>T p.E1354* | Nonsense Mutation (SNP) | VAF 64/197 reads (32%) | catalogued as COSV53346498, COSV99597461; called by muse, mutect2, varscan2
- PLCG2 | c.988T>C p.Y330H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV63868794; called by muse, mutect2, varscan2
- PLCG2 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63868801; called by muse, mutect2, varscan2
- PLEKHA6 | c.3014G>T p.R1005M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55332104; called by muse, mutect2, varscan2
- PLEKHG2 | c.3994C>T p.R1332W | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs560095135, COSV52681490; called by muse, mutect2, varscan2
- PLEKHH2 | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 53/149 reads (36%) | catalogued as COSV56752270, COSV56761117; called by muse, mutect2, varscan2
- PLXNA4 | c.4295C>T p.S1432L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58118513; called by muse, mutect2, varscan2
- PM20D1 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as COSV65648798; called by muse, mutect2, varscan2
- PNMA8A | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV58136612; called by muse, mutect2
- POLK | c.2009A>G p.N670S | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54034302; called by muse, mutect2, varscan2
- POLR3C | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 121/581 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782255927, COSV57906837; called by muse, mutect2, varscan2
- PPL | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV52167398; called by muse, mutect2, varscan2
- PPM1E | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV57573038; called by muse, mutect2, varscan2
- PPP1R9A | c.2953G>A p.V985I | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.32); catalogued as rs772043430, COSV56889489, COSV56915888; called by muse, mutect2, varscan2
- PRKN | c.1283dup p.N428Kfs*141 | Frame Shift Ins (INS) | VAF 50/151 reads (33%) | catalogued as rs758718482; called by mutect2, varscan2
- PRSS8 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896289; called by muse, mutect2
- PSD | c.2556G>T p.P852= | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as COSV50044626; called by muse, mutect2, varscan2
- PSMC3IP | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV53816888; called by muse, mutect2
- PTBP3 | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780793462, COSV57582032; called by muse, mutect2, varscan2
- PTEN | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1114167654, COSV64288532, COSV64295272; ClinVar: uncertain significance; called by muse, varscan2
- PTH2R | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs539493525, COSV55915443; called by muse, mutect2, varscan2
- PTPRF | c.3035A>G p.Q1012R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63444335; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 69/199 reads (35%) | catalogued as rs755727862; called by mutect2, varscan2
- QKI | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs1297474053, COSV51692368; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1892G>A p.G631E | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.311); catalogued as COSV62783278; called by muse, mutect2, varscan2
- RALB | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV55602695; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1166T>C p.V389A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV54575856; called by muse, mutect2, varscan2
- RAPGEF5 | c.1150G>A p.A384T (on ENST00000401957 / NM_001367602.2; = p.A687T on NM_012294.5) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV59781450; called by muse, mutect2, varscan2
- RASA1 | c.2039T>A p.L680* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV57194555, COSV57196634; called by muse, mutect2, varscan2
- RB1CC1 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as COSV50246241; called by muse, mutect2
- REN | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65817623; called by muse, mutect2
- RERGL | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs775606237, COSV57461580; called by muse, mutect2, varscan2
- RIN3 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.893); catalogued as rs769093908, COSV53647380; called by muse, mutect2, varscan2
- RNF139 | c.1390G>T p.V464F | Missense Mutation (SNP) | VAF 131/357 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52678966, COSV52681778; called by muse, mutect2, varscan2
- RNF148 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 118/415 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.735); catalogued as COSV57359213; called by muse, mutect2, varscan2
- RPGRIP1 | c.2108T>C p.I703T | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV52848343; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRAGB | c.325T>C p.S109P (on ENST00000262850 / NM_016656.4; = p.S81P on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53329298; called by muse, mutect2, varscan2
- RSAD2 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751694276, COSV65908220; called by muse, mutect2, varscan2
- RSKR | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56381656; called by muse, mutect2
- RSPH3 | c.1430C>T p.T477I (on ENST00000252655; = p.T335I on NM_031924.8) | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs367790514; called by muse, mutect2, varscan2
- RUSC2 | c.1753del p.A585Pfs*62 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV100771001; called by mutect2, pindel, varscan2
- RYR1 | c.8618C>A p.A2873D | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV62094767; called by muse, mutect2, varscan2
- SACS | c.12247G>A p.V4083I | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.13); catalogued as COSV66538511; called by muse, mutect2, varscan2
- SACS | c.9251T>C p.I3084T | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs149290718; called by muse, mutect2, varscan2
- SAMD7 | c.1285dup p.C429Lfs*9 | Frame Shift Ins (INS) | VAF 45/134 reads (34%) | catalogued as rs1311379305; called by mutect2, pindel, varscan2
- SC5D | c.39del p.F13Lfs*23 | Frame Shift Del (DEL) | VAF 39/135 reads (29%) | catalogued as rs1185907700; called by mutect2, pindel, varscan2
- SCAMP3 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); catalogued as COSV56944732; called by muse, mutect2, varscan2
- SCN1A | c.2396T>C p.V799A (on ENST00000303395 / NM_001202435.3; = p.V788A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as COSV57666877; called by muse, mutect2, varscan2
- SCN3A | c.5125G>A p.A1709T | Missense Mutation (SNP) | VAF 138/357 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51807442; called by muse, mutect2, varscan2
- SCN3A | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 145/411 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485299077, COSV51806715, COSV99327262; called by muse, mutect2, varscan2
- SEC24A | c.2756G>A p.R919H | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs538416137, COSV67305250; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 29/72 reads (40%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SERPINA11 | c.1097A>G p.E366G | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58241634; called by muse, mutect2, varscan2
- SERPINA3 | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67585888; called by muse, mutect2, varscan2
- SERPINA6 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV58584417; called by muse, mutect2, varscan2
- SERPINC1 | c.56dup p.L19Ffs*46 | Frame Shift Ins (INS) | VAF 44/247 reads (18%) | catalogued as CI024361; called by mutect2, pindel, varscan2
- SERPING1 | c.323A>G p.Q108R | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.231); catalogued as COSV53542216; called by muse, mutect2, varscan2
- SESN2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53427308; called by muse, mutect2, varscan2
- SETD7 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349071882, COSV56800032; called by muse, mutect2, varscan2
- SFMBT2 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs748712257, COSV62805508; called by muse, mutect2, varscan2
- SFMBT2 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV62805363, COSV62808311; called by muse, mutect2, varscan2
- SIGLEC8 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs779469110, COSV58473230; called by muse, mutect2, varscan2
- SKOR1 | c.2510A>G p.D837G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV58245233; called by muse, mutect2, varscan2
- SLAMF9 | c.5G>A p.C2Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs569464243, COSV63636576; called by muse, mutect2, varscan2
- SLC11A2 | c.799A>G p.K267E (on ENST00000394904 / NM_001379455.1; = p.K238E on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV50370296; called by muse, mutect2, varscan2
- SLC13A1 | c.640A>G p.S214G | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52010254; called by muse, mutect2, varscan2
- SLC17A5 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs545973; ClinVar: benign; called by muse, mutect2, varscan2
- SLC26A9 | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV61602126; called by muse, mutect2, varscan2
- SLC29A1 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs903981798, COSV57578019; called by muse, mutect2, varscan2
- SLC2A11 | c.1418G>T p.R473I (on ENST00000345044 / NM_001024938.4; = p.R480I on NM_030807.5) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV55390952; called by muse, mutect2, varscan2
- SLC32A1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs776433678, COSV54145946, COSV54146414; called by muse, mutect2, varscan2
- SLC34A1 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV60996431; called by muse, mutect2, varscan2
- SLC35C1 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.452); catalogued as COSV100029347, COSV58479784; called by muse, mutect2, varscan2
- SLC4A10 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV55774270; called by muse, mutect2, varscan2
- SLC7A3 | c.536T>A p.L179* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV53227140; called by muse, mutect2, varscan2
- SLC7A8 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0.03); catalogued as COSV57553744; called by muse, mutect2
- SLCO3A1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200042814, COSV59228648; called by muse, mutect2, varscan2
- SMC2 | c.1718A>G p.Y573C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.932); catalogued as rs905096447, COSV53957030; called by muse, mutect2, varscan2
- SMG7 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 124/558 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs558478492, COSV61630714; called by muse, mutect2, varscan2
- SNRK | c.842A>G p.N281S | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56067478; called by muse, mutect2, varscan2
- SNW1 | c.426+2T>A p.X142_splice | Splice Site (SNP) | VAF 178/672 reads (26%) | catalogued as COSV55053917; called by muse, mutect2, varscan2
- SOD2 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61622967; called by muse, mutect2
- SPAG4 | c.1178del p.P393Qfs*7 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs1292316291; called by mutect2, pindel, varscan2
- SPEF2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs552883814, COSV56795963; called by muse, mutect2, varscan2
- SPRR2B | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 132/647 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.407); catalogued as COSV58796972; called by muse, mutect2, varscan2
- SPRYD3 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs747328029, COSV56853377; called by muse, mutect2, varscan2
- SSTR1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as COSV57455412; called by muse, mutect2, varscan2
- ST7L | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58308300; called by muse, mutect2, varscan2
- STARD7 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61525442; called by muse, mutect2, varscan2
- SUPT16H | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1239184644, COSV53523880; called by muse, mutect2, varscan2
- SYNE2 | c.16889A>G p.Q5630R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV59947308; called by muse, mutect2, varscan2
- SYT2 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as COSV66141806; called by muse, mutect2, varscan2
- TAF1 | c.3482G>A p.R1161H (on ENST00000373790 / NM_138923.4; = p.R1182H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52111361, COSV99335726; called by muse, mutect2, varscan2
- TANC2 | c.5464G>A p.E1822K | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.114); catalogued as rs1184582533, COSV67333347; called by muse, mutect2, varscan2
- TBC1D2 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 194/486 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs549369882, COSV59784333; called by muse, mutect2, varscan2
- TDRD7 | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1564220709, COSV62428413; called by muse, mutect2, varscan2
- TENM3 | c.6368C>T p.A2123V | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV69305080; called by muse, mutect2, varscan2
- TESC | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs1243111559, COSV58811577; called by muse, mutect2, varscan2
- TET1 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs765094207, COSV65383974, COSV65389936; called by muse, mutect2, varscan2
- TET1 | c.4003C>T p.P1335S | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV65383976; called by muse, mutect2
- TLL2 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63571900; called by muse, mutect2, varscan2
- TMCC1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 46/95 reads (48%) | catalogued as COSV67872840; called by muse, mutect2, varscan2
- TMOD3 | c.282del p.I97Yfs*23 | Frame Shift Del (DEL) | VAF 82/242 reads (34%) | catalogued as rs759399045; called by mutect2, varscan2
- TMOD4 | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV54860206; called by muse, mutect2, varscan2
- TMPRSS7 | c.959G>T p.R320I (on ENST00000452346; = p.R194I on NM_001042575.2) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69980354; called by muse, mutect2, varscan2
- TNFRSF19 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs781557698, COSV50312663; called by muse, mutect2, varscan2
- TNS1 | c.4423G>A p.A1475T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs369175639, COSV50698031; called by muse, mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs758129598; called by mutect2, pindel, varscan2
- TOR1AIP2 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62625903; called by muse, mutect2, varscan2
- TP63 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM020797, COSV53196709, COSV53203439; called by muse, mutect2, varscan2
- TPM4 | c.*391-2A>G | Splice Site (SNP) | VAF 19/53 reads (36%) | catalogued as COSV56288588; called by muse, mutect2, varscan2
- TPO | c.2518G>T p.D840Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV61099787; called by muse, mutect2, varscan2
- TRAF3IP2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60675589, COSV60677277; called by muse, mutect2, varscan2
- TREML1 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV64191119; called by muse, mutect2
- TREX2 | c.295G>A p.V99I (on ENST00000334497; = p.V56I on NM_080701.3) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.37); catalogued as COSV57848453; called by muse, mutect2, varscan2
- TRIM33 | c.2399G>A p.G800D | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as COSV61822056; called by muse, mutect2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 67/195 reads (34%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIML1 | c.237G>T p.R79S | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV60194013; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs752676391; called by mutect2, varscan2
- TSPYL6 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs1423931033, COSV57812119; called by muse, mutect2, varscan2
- TSSK6 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs768155536, COSV53063230; called by muse, mutect2
- TTBK1 | c.3028G>A p.A1010T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs779381787, COSV52490310, COSV52490809; called by muse, mutect2, varscan2
- TTC21A | c.3380G>T p.R1127L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV56187819; called by muse, mutect2, varscan2
- TTC30B | c.893T>C p.M298T | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs1449288986, COSV68809372; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL13P | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747981327, COSV100296474, COSV60037030; called by muse, mutect2, varscan2
- TTN | c.78520A>G p.T26174A (on ENST00000591111; = p.T18750A on NM_003319.4) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | PolyPhen benign (0.02); catalogued as COSV59994466; called by muse, mutect2, varscan2
- TTN | c.54907G>A p.G18303S (on ENST00000591111; = p.G10879S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | PolyPhen probably damaging (0.979); catalogued as COSV59994495; called by muse, mutect2, varscan2
- TTN | c.54151A>G p.T18051A (on ENST00000591111; = p.T10627A on NM_003319.4) | Missense Mutation (SNP) | VAF 49/132 reads (37%) | PolyPhen benign (0.083); catalogued as rs771977738, COSV59994523; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTN | c.16750G>A p.V5584I (on ENST00000591111; = p.V4657I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/466 reads (3%) | PolyPhen benign (0.022); catalogued as COSV59994587; called by muse, mutect2
- TTN | c.15145G>A p.V5049M (on ENST00000591111; = p.V4122M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | PolyPhen benign (0.07); catalogued as rs372176136, COSV59994597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.1080dup p.T361Hfs*34 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs750889205; called by mutect2, pindel
- TXNDC16 | c.2332A>T p.K778* | Nonsense Mutation (SNP) | VAF 33/177 reads (19%) | catalogued as COSV55984238; called by muse, mutect2, varscan2
- U2SURP | c.814A>C p.S272R | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV67530576; called by muse, mutect2, varscan2
- UBN2 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 206/368 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56029678; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 70/187 reads (37%) | catalogued as rs763652408; called by mutect2, varscan2
- UBTD2 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67143193; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3370G>T p.E1124* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as COSV54436346; called by muse, mutect2, varscan2
- UNC79 | c.4847C>T p.S1616L (on ENST00000393151 / NM_001346218.2; = p.S1439L on NM_020818.5) | Missense Mutation (SNP) | VAF 118/466 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs760585021, COSV56383326; called by muse, mutect2
- USH2A | c.10924C>T p.Q3642* | Nonsense Mutation (SNP) | VAF 37/182 reads (20%) | catalogued as rs773462133, COSV56357450; called by muse, varscan2
- USH2A | c.5161G>T p.G1721* | Nonsense Mutation (SNP) | VAF 53/370 reads (14%) | catalogued as COSV56357461; called by muse, mutect2, varscan2
- UTRN | c.3521A>T p.D1174V | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV62332998; called by muse, mutect2, varscan2
- VCAN | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as rs201924385, COSV54103146; called by muse, mutect2, varscan2
- VPS33B | c.1658-1G>T p.X553_splice | Splice Site (SNP) | VAF 144/350 reads (41%) | catalogued as COSV60979837; called by muse, mutect2, varscan2
- VPS53 | c.171T>G p.S57= | Splice Region (SNP) | VAF 40/112 reads (36%) | catalogued as COSV52129097; called by muse, mutect2, varscan2
- WASHC2C | c.1547del p.K516Rfs*41 | Frame Shift Del (DEL) | VAF 72/263 reads (27%) | catalogued as rs782259587; called by mutect2, pindel, varscan2
- WDR35 | c.1586A>G p.Y529C (on ENST00000345530 / NM_001006657.2; = p.Y518C on NM_020779.4) | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55602038; called by muse, mutect2, varscan2
- WNK4 | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs764406058, COSV55903453; called by muse, mutect2, varscan2
- WWC3 | c.412T>C p.Y138H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1045984821, COSV66502646; called by muse, mutect2, varscan2
- WWC3 | c.2780G>A p.S927N | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101080981, COSV66502647; called by muse, mutect2, varscan2
- XIAP | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.437); catalogued as rs368511826, COSV63022134; called by muse, mutect2, varscan2
- XPO4 | c.2091G>T p.Q697H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55006427; called by muse, mutect2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | catalogued as rs762052135; called by mutect2, varscan2
- YEATS2 | c.3748A>G p.I1250V | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV59364378; called by muse, mutect2, varscan2
- YPEL5 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV54395171; called by muse, mutect2, varscan2
- ZADH2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs757530499, COSV59268284; called by muse, mutect2, varscan2
- ZBED4 | c.2551A>T p.S851C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53465161; called by muse, mutect2, varscan2
- ZC3HAV1 | c.435del p.F145Lfs*49 | Frame Shift Del (DEL) | VAF 37/182 reads (20%) | catalogued as rs1363033923; called by mutect2, varscan2
- ZCCHC14 | c.2752G>A p.A918T (on ENST00000268616; = p.A1055T on NM_015144.3) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51885452, COSV51887095; called by muse, mutect2, varscan2
- ZFC3H1 | c.4096A>G p.K1366E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66431758; called by muse, mutect2, varscan2
- ZFHX3 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV51715360; called by muse, mutect2, varscan2
- ZFHX4 | c.1780A>T p.T594S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as COSV50683246; called by muse, mutect2, varscan2
- ZNF2 | c.1130C>T p.T377I (on ENST00000611147 / NM_001291605.2; = p.T364I on NM_021088.4) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54636674; called by muse, mutect2, varscan2
- ZNF202 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV60246901; called by muse, mutect2, varscan2
- ZNF24 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 156/362 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV54348320; called by muse, mutect2, varscan2
- ZNF253 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 54/230 reads (23%) | catalogued as rs199597253; called by muse, mutect2, varscan2
- ZNF292 | c.6987A>T p.K2329N | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60538289; called by muse, mutect2, varscan2
- ZNF354C | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.131); catalogued as COSV59607925; called by muse, mutect2, varscan2
- ZNF438 | c.311A>G p.Q104R | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV59194183; called by muse, mutect2, varscan2
- ZNF496 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54176055; called by muse, mutect2, varscan2
- ZNF560 | c.2047A>C p.T683P | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56867218; called by muse, mutect2, varscan2
- ZNF628 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs759924406, COSV52698072; called by muse, mutect2, varscan2
- ZNF668 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs200991255, COSV100337010, COSV56213441; called by muse, mutect2, varscan2
- ZNF746 | c.523T>C p.S175P | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV61407087; called by muse, mutect2, varscan2
- ZP4 | c.553+2T>C p.X185_splice | Splice Site (SNP) | VAF 37/260 reads (14%) | catalogued as COSV63911692; called by muse, mutect2, varscan2
- ZSWIM5 | c.3308C>T p.T1103I | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as COSV55799850; called by muse, mutect2, varscan2
- AHNAK | c.9064del p.M3022Cfs*4 | Frame Shift Del (DEL) | VAF 107/338 reads (32%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.1349_1350del p.V450Afs*30 (on ENST00000458649 / NM_001367468.1; = p.V360Afs*30 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by pindel, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by mutect2, pindel, varscan2
- ARID5B | c.1677dup p.S560Qfs*9 | Frame Shift Ins (INS) | VAF 34/151 reads (23%) | called by mutect2, pindel, varscan2
- ATP6V0A4 | c.1746dup p.I583Yfs*20 | Frame Shift Ins (INS) | VAF 45/190 reads (24%) | called by mutect2, pindel, varscan2
- ATXN7L2 | c.1196dup p.D400* | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- CA12 | c.686del p.P229Lfs*42 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- CDC16 | c.1670dup p.N557Kfs*13 | Frame Shift Ins (INS) | VAF 52/174 reads (30%) | called by mutect2, pindel, varscan2
- CHMP7 | c.367del p.V123Lfs*6 | Frame Shift Del (DEL) | VAF 48/131 reads (37%) | called by mutect2, pindel, varscan2
- CLMN | c.2594del p.K865Rfs*10 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | called by mutect2, varscan2
- DDX5 | c.709del p.T237Pfs*3 | Frame Shift Del (DEL) | VAF 84/254 reads (33%) | called by mutect2, pindel, varscan2
- DENND5A | c.1137+2_1137+3del p.X379_splice | Splice Site (DEL) | VAF 52/116 reads (45%) | called by mutect2, pindel, varscan2
- DNAJC24 | c.99del p.K33Nfs*4 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- DPYSL3 | c.810dup p.G271Rfs*7 | Frame Shift Ins (INS) | VAF 61/192 reads (32%) | called by mutect2, pindel, varscan2
- ERBIN | c.2178dup p.D727Rfs*3 | Frame Shift Ins (INS) | VAF 74/232 reads (32%) | called by mutect2, pindel, varscan2
- ERN1 | c.813dup p.K272Qfs*51 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- GALNT5 | c.502dup p.A168Gfs*35 | Frame Shift Ins (INS) | VAF 51/176 reads (29%) | called by mutect2, pindel, varscan2
- GKN2 | c.139_140del p.N47Yfs*5 | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | called by mutect2, pindel, varscan2
- GMPPA | c.265dup p.L89Pfs*28 | Frame Shift Ins (INS) | VAF 32/107 reads (30%) | called by pindel, varscan2
- GTF2IRD2 | c.1148del p.G383Afs*8 | Frame Shift Del (DEL) | VAF 36/294 reads (12%) | called by mutect2, pindel
- GTF3C4 | c.1691dup p.I565Dfs*2 | Frame Shift Ins (INS) | VAF 35/151 reads (23%) | called by mutect2, varscan2
- JAK1 | c.2688del p.E897Kfs*14 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- JAK1 | c.1035del p.K345Nfs*32 | Frame Shift Del (DEL) | VAF 62/175 reads (35%) | called by mutect2, pindel, varscan2
- KIAA0319L | c.2532dup p.V845Cfs*14 | Frame Shift Ins (INS) | VAF 43/137 reads (31%) | called by mutect2, pindel, varscan2
- KLHL42 | c.614del p.G205Dfs*21 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- KRT73 | c.1156dup p.D386Gfs*13 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- LOXL3 | c.827del p.P276Lfs*4 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- LY96 | c.22del p.S8Pfs*45 | Frame Shift Del (DEL) | VAF 119/319 reads (37%) | called by mutect2, pindel, varscan2
- MAP1A | c.1248dup p.D417Rfs*18 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- MAP2K6 | c.941dup p.T315Hfs*4 | Frame Shift Ins (INS) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- MASTL | c.1372del p.I458Lfs*9 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | called by mutect2, varscan2
- MDC1 | c.3698dup p.N1233Kfs*2 | Frame Shift Ins (INS) | VAF 93/369 reads (25%) | called by mutect2, pindel, varscan2
- MDN1 | c.7848_7851del p.D2618Sfs*9 | Frame Shift Del (DEL) | VAF 127/355 reads (36%) | called by mutect2, pindel, varscan2
- MIDEAS | c.1974del p.I659Sfs*45 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- MRC1 | c.3521T>C p.V1174A | Missense Mutation (SNP) | VAF 186/525 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | called by mutect2, varscan2
- NAP1L4 | c.59del p.N20Mfs*12 | Frame Shift Del (DEL) | VAF 28/91 reads (31%) | called by mutect2, pindel, varscan2
- NEB | c.732del p.G245Vfs*18 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- NFE2L1 | c.485del p.P162Qfs*6 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- NLRP3 | c.2197del p.S733Qfs*3 | Frame Shift Del (DEL) | VAF 122/332 reads (37%) | called by mutect2, pindel, varscan2
- NOL6 | c.2857del p.Q953Kfs*32 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, varscan2
- NSD1 | c.5397del p.F1799Lfs*22 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | called by mutect2, pindel, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | called by mutect2, varscan2
- OSBPL8 | c.1519del p.Y507Ifs*45 | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.965del p.N322Mfs*42 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | called by mutect2, varscan2
- PSME4 | c.2281del p.D761Tfs*54 | Frame Shift Del (DEL) | VAF 53/173 reads (31%) | called by mutect2, pindel, varscan2
- PTCD1 | c.1335del p.A447Pfs*12 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- PUS1 | c.1267del p.D423Tfs*123 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- RBL2 | c.1537dup p.R513Kfs*26 | Frame Shift Ins (INS) | VAF 39/113 reads (35%) | called by mutect2, pindel, varscan2
- RPS6KA3 | c.324del p.V109Ffs*15 | Frame Shift Del (DEL) | VAF 83/260 reads (32%) | called by mutect2, pindel, varscan2
- SCG3 | c.873dup p.E292Rfs*17 | Frame Shift Ins (INS) | VAF 34/122 reads (28%) | called by mutect2, pindel, varscan2
- SCLT1 | c.167del p.L56* | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- SEMA5B | c.983del p.G328Afs*13 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- SEPHS1 | c.1168del p.A390Pfs*41 | Frame Shift Del (DEL) | VAF 83/263 reads (32%) | called by mutect2, pindel, varscan2
- SIN3A | c.1401del p.F467Lfs*28 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | called by mutect2, varscan2
- SLC25A25 | c.364del p.I122Ffs*11 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- SLC30A7 | c.840_842+1delinsT p.X280_splice | Splice Site (DEL) | VAF 28/85 reads (33%) | called by pindel, varscan2*
- SMARCA2 | c.1673_1675dup p.K558dup | In Frame Ins (INS) | VAF 18/47 reads (38%) | called by mutect2, varscan2
- SOS2 | c.1598del p.N533Tfs*16 | Frame Shift Del (DEL) | VAF 84/346 reads (24%) | called by mutect2, pindel, varscan2
- SULT1C3 | c.20del p.N7Tfs*17 | Frame Shift Del (DEL) | VAF 43/135 reads (32%) | called by mutect2, pindel, varscan2
- SYCP2 | c.3005dup p.M1003Dfs*24 | Frame Shift Ins (INS) | VAF 25/75 reads (33%) | called by mutect2, pindel, varscan2
- TEX10 | c.13del p.R5Efs*10 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- THOC2 | c.2505del p.K835Nfs*22 | Frame Shift Del (DEL) | VAF 95/297 reads (32%) | called by mutect2, pindel, varscan2
- TMEM161B | c.1343del p.N448Ifs*15 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | called by mutect2, pindel, varscan2
- TPR | c.645del p.N217Mfs*4 | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | called by mutect2, pindel, varscan2
- TRIM4 | c.1118del p.N373Tfs*57 | Frame Shift Del (DEL) | VAF 294/1171 reads (25%) | called by mutect2, pindel, varscan2
- TXLNA | c.281del p.G94Afs*35 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- UBB | c.680dup p.G228Wfs*38 | Frame Shift Ins (INS) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- UGP2 | c.520del p.I174Yfs*10 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- URGCP | c.1793del p.G598Afs*14 (on ENST00000453200 / NM_001077663.3; = p.G589Afs*14 on NM_017920.4) | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- UROC1 | c.920dup p.E308Gfs*171 | Frame Shift Ins (INS) | VAF 26/84 reads (31%) | called by mutect2, varscan2
- USP9X | c.3542_3543del p.V1181Efs*12 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | called by pindel, varscan2
- WDR83 | c.941_*8del | Nonstop Mutation (DEL) | VAF 23/49 reads (47%) | called by mutect2, pindel, varscan2
- XYLT1 | c.2696del p.G899Afs*85 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- ABCD4 | c.808C>T p.L270= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV53991950; called by muse, mutect2, varscan2
- ADAM15 | c.87T>C p.T29= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV55058487; called by muse, mutect2, varscan2
- ADCY7 | c.1641C>T p.D547= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs779459779, COSV54265946; called by muse, mutect2, varscan2
- ADGRV1 | c.9018G>A p.G3006= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV67983345; called by muse, mutect2, varscan2
- AGXT2 | c.1005C>T p.G335= | Silent (SNP) | VAF 12/294 reads (4%) | catalogued as COSV51485590; called by muse, mutect2
- AL136295.1 | c.1242C>T p.S414= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs765377419, COSV55779265; called by muse, mutect2
- AMOTL2 | c.2142C>A p.P714= (on ENST00000422605; = p.P715= on NM_016201.4) | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV51438643; called by muse, mutect2, varscan2
- ANOS1 | c.231C>T p.C77= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV52918485; called by muse, mutect2, varscan2
- APOA4 | c.792G>A p.R264= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV63360332; called by muse, mutect2, varscan2
- ARHGEF9 | c.729G>A p.V243= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV53637223; called by muse, mutect2, varscan2
- ARMC6 | c.1215C>T p.S405= (on ENST00000392336; = p.S380= on NM_033415.4) | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2
- ATP10B | c.771T>C p.P257= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV58778442; called by muse, mutect2, varscan2
- BCL9 | c.3438T>C p.S1146= | Silent (SNP) | VAF 46/256 reads (18%) | catalogued as COSV52343065; called by muse, mutect2, varscan2
- CASP2 | c.1101C>T p.G367= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as COSV60081825; called by muse, mutect2, varscan2
- CFAP251 | c.2685C>T p.A895= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs371782690; called by muse, mutect2, varscan2
- CHRNB4 | c.1272G>A p.V424= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs776866735, COSV55715667; called by muse, mutect2, varscan2
- CLIP4 | c.462G>A p.L154= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs781539688, COSV60748719; called by muse, mutect2, varscan2
- CLN8 | c.729A>T p.L243= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV58670229; called by muse, mutect2, varscan2
- CNTN6 | c.1126C>T p.L376= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV63168981; called by muse, mutect2, varscan2
- COL5A3 | c.804G>A p.K268= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs1197179768, COSV53409348; called by muse, mutect2
- COL5A3 | c.525C>T p.G175= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV53409360; called by muse, mutect2, varscan2
- COL6A3 | c.7212C>A p.A2404= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV55086505; called by muse, mutect2, varscan2
- CTC1 | c.3447C>A p.P1149= | Silent (SNP) | VAF 9/163 reads (6%) | catalogued as COSV59852970; called by muse, mutect2
- DACT1 | c.1671C>T p.A557= | Silent (SNP) | VAF 54/99 reads (55%) | catalogued as COSV60020377; called by muse, mutect2, varscan2
- DAG1 | c.1017G>T p.V339= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as COSV58183650; called by muse, mutect2, varscan2
- DCC | c.1821C>T p.G607= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs370522780; called by muse, mutect2, varscan2
- DCHS1 | c.1848C>A p.S616= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as COSV55034148; called by muse, mutect2
- DDR1 | c.1878G>A p.L626= (on ENST00000324771; = p.L589= on NM_001954.4) | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as COSV61320680; called by muse, mutect2, varscan2
- DENND4B | c.3651C>A p.A1217= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV63408421; called by muse, mutect2, varscan2
- DIAPH2 | c.1002T>C p.N334= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV61266206; called by muse, mutect2, varscan2
- DIAPH3 | c.963C>T p.D321= (on ENST00000400324 / NM_001042517.2; = p.D58= on NM_030932.3) | Silent (SNP) | VAF 79/213 reads (37%) | catalogued as COSV57368621; called by muse, mutect2, varscan2
- DIP2B | c.3255G>A p.T1085= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs368662580; called by muse, mutect2, varscan2
- DIS3 | c.1524T>C p.D508= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as COSV66706159; called by muse, mutect2, varscan2
- DMTF1 | c.1179C>T p.N393= | Silent (SNP) | VAF 71/232 reads (31%) | catalogued as COSV58684561; called by muse, mutect2, varscan2
- DPEP3 | c.252G>A p.A84= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV52051053; called by muse, mutect2
- DPY19L1 | c.528A>T p.I176= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV60581576, COSV60581825; called by muse, mutect2, varscan2
- DSCC1 | c.699C>T p.L233= | Silent (SNP) | VAF 89/261 reads (34%) | catalogued as rs1038172754, COSV58086830; called by muse, mutect2, varscan2
- DZIP1L | c.843C>T p.V281= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as rs747418381, COSV59519841, COSV59520261; called by muse, mutect2, varscan2
- EML5 | c.2607A>T p.A869= | Silent (SNP) | VAF 193/678 reads (28%) | catalogued as COSV61344443; called by muse, mutect2, varscan2
- EPC1 | c.1608A>G p.L536= | Silent (SNP) | VAF 47/147 reads (32%) | catalogued as rs749673365, COSV53924928; called by muse, mutect2, varscan2
- EPHB6 | c.1854C>A p.V618= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV63891359, COSV63892979; called by muse, varscan2
- F13B | c.543T>C p.A181= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as COSV66373410; called by muse, mutect2, varscan2
- FAM120B | c.405A>G p.S135= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV53003115; called by muse, mutect2, varscan2
- FAM47B | c.402C>T p.Y134= | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as COSV61453336; called by muse, mutect2
- FBN3 | c.855C>T p.A285= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs751067216, COSV54458469; called by muse, mutect2, varscan2
- FBXO32 | c.417C>T p.G139= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV54890790; called by muse, mutect2, varscan2
- FGF5 | c.51C>T p.S17= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs1187108915, COSV56889763; called by muse, mutect2, varscan2
- FNBP4 | c.2742T>A p.P914= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs764692178, COSV55447882; called by muse, mutect2
- G3BP1 | c.531A>T p.A177= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as COSV62365966; called by muse, mutect2, varscan2
- GALR2 | c.555C>T p.R185= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV57161586; called by muse, mutect2
- GCHFR | c.222C>T p.G74= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV53066828; called by muse, mutect2, varscan2
- GDF6 | c.342T>C p.N114= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV54624384; called by muse, mutect2
- GGNBP2 | c.2085A>C p.G695= | Silent (SNP) | VAF 59/125 reads (47%) | called by muse, mutect2, varscan2
- GIMAP6 | c.510C>T p.G170= | Silent (SNP) | VAF 73/256 reads (29%) | catalogued as rs145423565; called by muse, mutect2, varscan2
- GLUL | c.756C>T p.C252= | Silent (SNP) | VAF 51/202 reads (25%) | catalogued as rs369513842; called by muse, mutect2, varscan2
- GPCPD1 | c.1233T>C p.T411= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV66830580; called by muse, mutect2
- GPR176 | c.1338T>C p.P446= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs573817271, COSV54444553; called by muse, mutect2, varscan2
- GPR37L1 | c.693G>A p.V231= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV66162134; called by muse, mutect2, varscan2
- GRB10 | c.612G>A p.V204= | Silent (SNP) | VAF 47/234 reads (20%) | catalogued as COSV60009583; called by muse, mutect2, varscan2
- GRPR | c.528C>T p.A176= | Silent (SNP) | VAF 63/275 reads (23%) | catalogued as rs753452609, COSV66669174; called by muse, mutect2, varscan2
- HAS3 | c.321G>A p.S107= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs779449697, COSV54706657; called by muse, mutect2, varscan2
- HYOU1 | c.2610A>G p.A870= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV68215577; called by muse, mutect2, varscan2
- IL11RA | c.408G>A p.Q136= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV52404831; called by muse, mutect2, varscan2
- INTS6 | c.2565A>G p.A855= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs1016895168, COSV60877597; called by muse, mutect2, varscan2
- KALRN | c.135C>T p.F45= | Silent (SNP) | VAF 82/239 reads (34%) | catalogued as rs267599579, COSV53755729; called by muse, mutect2, varscan2
- KBTBD3 | c.537T>C p.H179= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV73241349; called by muse, mutect2, varscan2
- KDM3B | c.1698A>G p.S566= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV58689870; called by muse, mutect2, varscan2
- LAMB3 | c.1698G>A p.Q566= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV61916394; called by muse, mutect2, varscan2
- LSS | c.2115G>T p.T705= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV62700630; called by muse, mutect2, varscan2
- LTF | c.1719T>C p.T573= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV51607231; called by muse, mutect2, varscan2
- LY75-CD302 | c.5007T>C p.T1669= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs374632188; called by muse, mutect2, varscan2
- MAGEA3 | c.456C>T p.S152= | Silent (SNP) | VAF 65/204 reads (32%) | catalogued as COSV64755987; called by muse, mutect2, varscan2
- MAGEC3 | c.423T>C p.S141= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV53578904; called by muse, mutect2, varscan2
- MAST4 | c.4203A>G p.G1401= (on ENST00000403625 / NM_001164664.2; = p.G1212= on NM_015183.3) | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV55122192; called by muse, mutect2, varscan2
- MBTPS2 | c.585T>C p.I195= | Silent (SNP) | VAF 77/194 reads (40%) | catalogued as COSV63411166; called by muse, mutect2, varscan2
- MFSD6 | c.621T>C p.N207= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as rs762231515, COSV55622190; called by muse, mutect2, varscan2
- MGA | c.7299G>A p.R2433= (on ENST00000219905 / NM_001164273.1; = p.R2224= on NM_001080541.2) | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as COSV54952175; called by muse, mutect2, varscan2
- MGAM | c.3342C>A p.T1114= | Silent (SNP) | VAF 78/158 reads (49%) | catalogued as COSV72074459; called by muse, mutect2
- MICAL2 | c.4344G>A p.E1448= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV56285473; called by muse, mutect2, varscan2
- MMP24 | c.747C>T p.G249= | Silent (SNP) | VAF 90/265 reads (34%) | catalogued as COSV55769462; called by muse, mutect2, varscan2
- MORC1 | c.354G>A p.T118= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs555321094, COSV51713642; called by muse, mutect2, varscan2
- MSANTD3 | c.513G>A p.S171= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs61744816, COSV58492498; called by muse, mutect2, varscan2
- MTA1 | c.888C>T p.F296= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs146792849; called by muse, mutect2
- MTA2 | c.256C>A p.R86= | Silent (SNP) | VAF 91/245 reads (37%) | catalogued as COSV53871197, COSV53871641; called by muse, mutect2, varscan2
- MTREX | c.18A>G p.G6= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV52417789; called by muse, mutect2
- MUC4 | c.13872G>C p.G4624= (on ENST00000463781 / NM_018406.7; = p.G388= on NM_004532.6) | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV57776547; called by muse, mutect2
- MUSK | c.2004C>T p.R668= | Silent (SNP) | VAF 76/213 reads (36%) | catalogued as COSV51883573; called by muse, mutect2, varscan2
- MYO15A | c.8613C>T p.Y2871= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs548822110, COSV52755243; called by muse, mutect2, varscan2
- NLE1 | c.1089G>A p.K363= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV50101147; called by muse, mutect2, varscan2
- NOS1 | c.3738A>G p.Q1246= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV57610635; called by muse, mutect2, varscan2
- NSD1 | c.4878T>G p.T1626= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV61774845; called by muse, mutect2, varscan2
- NUP160 | c.1896A>G p.L632= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs779456467, COSV65854089; called by muse, mutect2, varscan2
- NWD1 | c.4059C>T p.S1353= | Silent (SNP) | VAF 52/173 reads (30%) | catalogued as rs776166331, COSV60340942; called by muse, mutect2, varscan2
- ODF2 | c.102C>T p.G34= (on ENST00000434106 / NM_153433.2; = p.G78= on NM_153432.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs985851112, COSV63546595; called by muse, mutect2, varscan2
- OR2T33 | c.435G>A p.S145= | Silent (SNP) | VAF 50/452 reads (11%) | catalogued as rs755954026, COSV58815060; called by muse, varscan2
- PAXIP1 | c.1947G>A p.T649= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs759650347, COSV68184588; called by muse, mutect2, varscan2
- PBX3 | c.966T>C p.A322= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV60731699; called by muse, mutect2
- PCDH11X | c.3951A>G p.S1317= | Silent (SNP) | VAF 118/317 reads (37%) | catalogued as rs753314502, COSV53458295; called by muse, mutect2, varscan2
- PCDH18 | c.1404C>T p.S468= | Silent (SNP) | VAF 105/241 reads (44%) | catalogued as rs749185256, COSV61267635; called by muse, mutect2, varscan2
- PCDH19 | c.3069C>T p.S1023= (on ENST00000373034 / NM_001184880.2; = p.S975= on NM_020766.3) | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as rs751256749, COSV55261193; called by muse, mutect2, varscan2
- PCMTD2 | c.981G>A p.P327= | Silent (SNP) | VAF 108/243 reads (44%) | catalogued as rs529111736, COSV55060138, COSV99829565; called by muse, mutect2, varscan2
- PDP1 | c.573G>A p.Q191= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV52601112; called by muse, mutect2, varscan2
- PDPN | c.213T>C p.S71= (on ENST00000621990; = p.S147= on NM_006474.4) | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as COSV53847743; called by muse, mutect2, varscan2
- PIAS2 | c.426C>T p.V142= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as COSV61342913; called by muse, mutect2, varscan2
- PIAS4 | c.288G>T p.V96= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV53678768; called by muse, mutect2, varscan2
- PLBD1 | c.162A>G p.V54= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV53692830; called by muse, mutect2, varscan2
- PLCD4 | c.1215G>A p.E405= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs747595034, COSV68842428; called by muse, mutect2, varscan2
- PPP2R3B | c.420C>T p.N140= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs776346158, COSV66813105; called by muse, mutect2
- PRICKLE1 | c.342T>C p.I114= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV61542817; called by muse, mutect2, varscan2
- PRKCG | c.1308C>T p.Y436= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs955612922, COSV54726724; called by muse, mutect2, varscan2
- PRRT1 | c.765C>T p.R255= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1236077578, COSV52998024, COSV52998396; called by muse, mutect2, varscan2
- PSIP1 | c.663G>A p.G221= | Silent (SNP) | VAF 156/477 reads (33%) | catalogued as COSV66254294; called by muse, mutect2, varscan2
- PTPN2 | c.558T>C p.P186= | Silent (SNP) | VAF 59/262 reads (23%) | catalogued as COSV58996337; called by muse, mutect2, varscan2
- QARS1 | c.2121G>A p.V707= | Silent (SNP) | VAF 41/143 reads (29%) | catalogued as COSV60274658; called by muse, mutect2, varscan2
- QSOX1 | c.1029C>T p.G343= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV62580207; called by muse, mutect2
- RAPGEF3 | c.2196C>A p.A732= (on ENST00000389212; = p.A690= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- RBFOX1 | c.1017C>T p.A339= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs148909710; called by muse, mutect2, varscan2
- RBMXL1 | c.252C>T p.A84= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV53100348; called by muse, mutect2, varscan2
- RC3H1 | c.375T>A p.T125= | Silent (SNP) | VAF 78/439 reads (18%) | catalogued as COSV51199628; called by muse, mutect2, varscan2
- RHOU | c.492T>C p.D164= | Silent (SNP) | VAF 84/391 reads (21%) | catalogued as COSV64208523; called by muse, mutect2, varscan2
- RO60 | c.1404T>A p.T468= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as COSV66473608; called by muse, mutect2, varscan2
- RP1L1 | c.1797G>A p.E599= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs750623624, COSV66754128; called by muse, mutect2, varscan2
- RRP9 | c.1341C>A p.G447= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV51753883; called by muse, mutect2, varscan2
- RXRB | c.1389G>A p.L463= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV59495864; called by muse, mutect2, varscan2
- RYR2 | c.4479C>T p.S1493= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as COSV63679475; called by muse, mutect2, varscan2
- SDR9C7 | c.399C>T p.N133= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV53288954; called by muse, mutect2, varscan2
- SEC31A | c.1260G>A p.Q420= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV52344267; called by muse, mutect2
- SEMA4A | c.588T>C p.G196= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as COSV61772513; called by muse, mutect2
- SETBP1 | c.3324G>A p.K1108= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as COSV56319243; called by muse, mutect2
- SIX4 | c.1206C>T p.S402= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as COSV53669280; called by muse, mutect2, varscan2
- SLAMF1 | c.465C>T p.N155= | Silent (SNP) | VAF 91/309 reads (29%) | catalogued as rs773729465, COSV52498867; called by muse, mutect2, varscan2
- SLC12A8 | c.615G>A p.L205= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV58865294; called by muse, mutect2, varscan2
- SLC35F4 | c.1533A>G p.R511= (on ENST00000339762 / NM_001352015.2; = p.R475= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as COSV60263944; called by muse, mutect2, varscan2
- SLC52A1 | c.516C>T p.C172= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs779404952, COSV54692781; called by muse, mutect2, varscan2
- SNRNP200 | c.3912G>A p.L1304= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV60489174; called by muse, mutect2, varscan2
- SRPX | c.123C>T p.D41= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs768531810, COSV59438113; called by muse, mutect2, varscan2
- SSBP2 | c.891A>G p.L297= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV57796076; called by muse, mutect2, varscan2
- ST6GAL2 | c.189C>T p.G63= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV64527677, COSV64527700; called by muse, mutect2, varscan2
- ST8SIA2 | c.688C>T p.L230= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs762146731, COSV51568677; called by muse, mutect2, varscan2
- SYT17 | c.474A>G p.E158= | Silent (SNP) | VAF 67/235 reads (29%) | catalogued as COSV62545852; called by muse, mutect2, varscan2
- TAF4 | c.1836G>A p.Q612= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV53336803; called by muse, mutect2, varscan2
- TAS2R30 | c.750T>C p.C250= | Silent (SNP) | VAF 12/441 reads (3%) | catalogued as COSV67855061; called by muse, mutect2
- TEAD2 | c.1251C>A p.T417= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV60544127; called by muse, mutect2, varscan2
- TENT5A | c.1101G>A p.V367= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV60787795; called by muse, mutect2, varscan2
- TGFBR3 | c.1719C>T p.S573= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as COSV53024434; called by muse, mutect2, varscan2
- TMEM263 | c.264T>C p.S88= | Silent (SNP) | VAF 64/159 reads (40%) | catalogued as COSV55013898; called by muse, mutect2, varscan2
- TMUB1 | c.246G>A p.Q82= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV52539764; called by muse, mutect2, varscan2
- TNPO2 | c.361C>T p.L121= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV63508044; called by muse, mutect2, varscan2
- TNRC6A | c.1188T>C p.S396= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV59363140; called by muse, mutect2, varscan2
- TOGARAM1 | c.372C>T p.G124= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV61887896; called by muse, mutect2, varscan2
- TRBV4-1 | c.264C>A p.P88= | Silent (SNP) | VAF 191/324 reads (59%) | called by muse, mutect2, varscan2
- TRO | c.873A>G p.S291= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV51500350; called by muse, mutect2, varscan2
- TRPC3 | c.900C>T p.L300= (on ENST00000379645 / NM_001366479.2; = p.L227= on NM_003305.2) | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV53374331; called by muse, mutect2, varscan2
- TSEN34 | c.309G>A p.E103= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV55475323; called by muse, mutect2, varscan2
- TTLL9 | c.1254C>T p.N418= | Silent (SNP) | VAF 73/204 reads (36%) | catalogued as rs1230173477, COSV52431219; called by muse, mutect2, varscan2
- TTN | c.39189C>T p.H13063= (on ENST00000591111; = p.H5639= on NM_003319.4) | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs754693395, COSV59994553; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- UBR4 | c.14365C>A p.R4789= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV64387292; called by muse, mutect2, varscan2
- USF3 | c.6021T>C p.F2007= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV57071711; called by muse, mutect2, varscan2
- WNK4 | c.1020G>A p.P340= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1348436147, COSV53820418; called by muse, mutect2, varscan2
- XBP1 | c.630T>G p.T210= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV53274736; called by muse, mutect2, varscan2
- XIRP2 | c.4479T>C p.S1493= (on ENST00000628543; = p.S1668= on NM_152381.6) | Silent (SNP) | VAF 94/303 reads (31%) | catalogued as COSV54694216; called by muse, mutect2, varscan2
- XIRP2 | c.8583C>A p.S2861= (on ENST00000628543; = p.S3036= on NM_152381.6) | Silent (SNP) | VAF 142/383 reads (37%) | catalogued as COSV54694229; called by muse, mutect2, varscan2
- ZBTB3 | c.124C>T p.L42= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs1392514160, COSV67361137; called by muse, mutect2, varscan2
- ZCCHC7 | c.1631A>G p.*544= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV60956619; called by muse, mutect2, varscan2
- ZFHX4 | c.7392G>T p.S2464= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as rs761611371, COSV50650716, COSV50683357; called by muse, mutect2, varscan2
- ZFP42 | c.225C>T p.C75= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as rs369075421, COSV58816454; called by muse, mutect2, varscan2
- ZHX2 | c.114A>G p.P38= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs775017099, COSV58712112; called by muse, mutect2, varscan2
- ZKSCAN1 | c.450T>A p.P150= | Silent (SNP) | VAF 57/171 reads (33%) | catalogued as COSV60873660; called by muse, mutect2, varscan2
- ZMIZ2 | c.1761C>T p.D587= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs778824056, COSV54807233; called by muse, mutect2, varscan2
- ZNF292 | c.735C>T p.I245= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as rs747332293, COSV60538276; called by muse, mutect2, varscan2
- ZNF326 | c.1116G>A p.K372= | Silent (SNP) | VAF 92/220 reads (42%) | catalogued as COSV61035015; called by muse, mutect2, varscan2
- ZNF33B | c.2193C>T p.Y731= | Silent (SNP) | VAF 11/374 reads (3%) | catalogued as rs866841848, COSV63942284; called by muse, mutect2
- ZNF490 | c.1071C>T p.T357= | Silent (SNP) | VAF 87/274 reads (32%) | catalogued as rs140333364; called by muse, mutect2, varscan2
- ZNF516 | c.1920C>T p.G640= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as COSV71586911; called by muse, mutect2, varscan2
- ZNF518A | c.3459T>C p.N1153= | Silent (SNP) | VAF 55/167 reads (33%) | catalogued as COSV60151089; called by muse, mutect2, varscan2
- ZNF658 | c.1413T>C p.N471= | Silent (SNP) | VAF 53/203 reads (26%) | called by muse, mutect2, varscan2
- ZSCAN22 | c.918C>T p.S306= | Silent (SNP) | VAF 7/160 reads (4%) | catalogued as COSV61638981; called by muse, mutect2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 12/84 reads (14%) | catalogued as rs766264675; called by pindel, varscan2
- AL353804.4 | chrX:73823055 del T | 5'Flank (DEL) | VAF 61/187 reads (33%) | catalogued as rs755255238; called by mutect2, varscan2
- AL353804.6 | chrX:73826754 C>A | 3'Flank (SNP) | VAF 97/259 reads (37%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852700 G>C | 3'Flank (SNP) | VAF 5/13 reads (38%) | catalogued as rs767540589; called by muse, mutect2, varscan2
- C3orf35 | chr3:37417382 A>C | 3'Flank (SNP) | VAF 59/198 reads (30%) | called by muse, mutect2, varscan2
- CLCN5 | c.17-38736T>C | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as COSV65800897; called by muse, mutect2, varscan2
- KIF1B | c.2115+6780T>G | Intron (SNP) | VAF 74/263 reads (28%) | catalogued as COSV55807402; called by muse, mutect2, varscan2
- MIR365B | n.82del | RNA (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- NACA | c.71-4858C>A | Intron (SNP) | VAF 15/42 reads (36%) | catalogued as COSV63269331; called by muse, mutect2, varscan2
- NEBL | c.164+46446A>G | Intron (SNP) | VAF 81/184 reads (44%) | catalogued as COSV65798284; called by muse, mutect2
- NFASC | c.2471-1416C>T | Intron (SNP) | VAF 18/71 reads (25%) | catalogued as COSV58363725; called by muse, mutect2, varscan2
- NRP1 | c.1759+1344T>G | Intron (SNP) | VAF 23/69 reads (33%) | catalogued as COSV55164253; called by muse, mutect2, varscan2
10 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 10 other) are not listed here.
